Somatic mutation profile of tumor specimen TCGA-XV-AAZW-01A (aliquot TCGA-XV-AAZW-01A-12D-A401-08) from TCGA case TCGA-XV-AAZW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 62.4 years (22,778 days).
Specimen TCGA-XV-AAZW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ab9f653-c484-48a1-b98a-bdc1e88bb27b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XV-AAZW-10A (Blood Derived Normal), aliquot TCGA-XV-AAZW-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/942067f0-37ff-4db9-b849-4f3ba7caf8a5

The open-access MAF lists 193 somatic variants for this specimen: 121 protein-altering or splice-affecting, 65 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 65, Nonsense Mutation 7, Intron 3, Splice Region 3, Translation Start Site 2, Frame Shift Del 2, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CEP290 | c.5344C>T p.R1782* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs575767207, CM106967, COSV100469412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACA | c.6695G>A p.R2232Q | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1232687330; called by muse, mutect2, varscan2
- ACSM1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54632909, COSV99533646; called by muse, mutect2, varscan2
- ADGRG4 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV54950738; called by muse, mutect2, varscan2
- AMELX | c.14T>A p.I5N | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as CD951571, COSV100498779; called by muse, mutect2, varscan2
- AMY2A | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 83/630 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101340628, COSV70214217; called by muse, mutect2, varscan2
- ANK2 | c.10480C>T p.Q3494* | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100003194; called by muse, mutect2, varscan2
- ANKLE2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1218415939, COSV100514275; called by muse, mutect2, varscan2
- ARID3C | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs760628147, COSV99426989; called by muse, mutect2, varscan2
- ASXL3 | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs867039549, COSV52475488; called by muse, mutect2, varscan2
- ATP2B1 | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1433458409, COSV99665985; called by muse, mutect2, varscan2
- BNIP5 | c.1290G>T p.R430S | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV101465102, COSV101465199; called by muse, mutect2, varscan2
- BPIFB1 | c.155T>A p.I52N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99487557; called by muse, mutect2, varscan2
- BRCA2 | c.5105C>T p.P1702L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV66462273; called by muse, mutect2, varscan2
- BRINP3 | c.72T>A p.S24R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.278); catalogued as COSV100819182; called by muse, mutect2, varscan2
- C11orf45 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV100171578; called by muse, mutect2, varscan2
- CACNA1E | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770435124, COSV62412751; called by muse, mutect2, varscan2
- CAMTA2 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.988); catalogued as rs1463860330, COSV61835053; called by muse, mutect2, varscan2
- CARMIL2 | c.2140A>T p.T714S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100576183; called by muse, mutect2, varscan2
- CEP192 | c.3954C>G p.I1318M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as COSV100381780; called by muse, mutect2, varscan2
- CERS3 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1238919586, COSV99432462; called by muse, mutect2, varscan2
- CES5A | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99307869; called by muse, mutect2, varscan2
- CFAP47 | c.4951G>A p.E1651K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100545603; called by muse, mutect2, varscan2
- CLCNKA | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100510269; called by muse, mutect2, varscan2
- COPS7A | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs755340818, COSV57526287; called by muse, mutect2, varscan2
- CWH43 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs548931558, COSV56939731; called by muse, mutect2, varscan2
- CYP3A4 | c.1514C>T p.P505L (on ENST00000336411; = p.P474L on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/128 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV100315800; called by muse, mutect2, varscan2
- CYRIA | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV100838514; called by muse, mutect2, varscan2
- DCBLD1 | c.1204A>G p.R402G | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as COSV99757916; called by muse, mutect2, varscan2
- DGKB | c.1496C>T p.T499I | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs949395139, COSV51796606, COSV99342023; called by muse, mutect2, varscan2
- DIAPH2 | c.1614G>A p.Q538= | Splice Region (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100234407; called by muse, mutect2, varscan2
- DLC1 | c.1681G>A p.D561N (on ENST00000276297 / NM_001348081.2; = p.D124N on NM_006094.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs375115845; called by muse, mutect2, varscan2
- DLL4 | c.1704G>A p.M568I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs1364041754, COSV99989930; called by muse, varscan2
- DNAH11 | c.2599G>A p.G867S | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100180094; called by muse, mutect2, varscan2
- EBF1 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as rs1215590199, COSV58167520; called by muse, mutect2, varscan2
- FARSA | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100108979; called by muse, mutect2, varscan2
- FAT3 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53137083; called by muse, mutect2, varscan2
- FLG2 | c.4220G>A p.G1407E | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV101166068, COSV66171045; called by muse, mutect2, varscan2
- FNDC1 | c.2064C>G p.H688Q | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99796347; called by muse, mutect2, varscan2
- FUT9 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 87/107 reads (81%) | SIFT tolerated (0.51); PolyPhen benign (0.103); catalogued as COSV56142605; called by muse, mutect2, varscan2
- GABRG3 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61539987; called by muse, mutect2
- GPR132 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.116); catalogued as rs558947453, COSV61677499; called by muse, mutect2, varscan2
- GPR84 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0.053); catalogued as COSV99910082, COSV99910105; called by muse, mutect2, varscan2
- GPRIN1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs530711230, COSV99991976; called by muse, mutect2, varscan2
- HIVEP3 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV99913475; called by muse, mutect2, varscan2
- HLA-DPB1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101331042; called by muse, mutect2, varscan2
- HYDIN | c.8520C>A p.Y2840* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1197753609, COSV99993391; called by muse, mutect2, varscan2
- IGSF1 | c.3962C>T p.P1321L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as COSV100812210; called by muse, mutect2, varscan2
- IL7R | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100286485, COSV57405791; called by muse, mutect2, varscan2
- KCNJ5 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV57965533; called by muse, mutect2, varscan2
- KCNK10 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1388738317, COSV100068090; called by muse, mutect2
- KMT2C | c.8626G>A p.D2876N | Missense Mutation (SNP) | VAF 70/101 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100074853; called by muse, mutect2, varscan2
- KRT5 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603519, COSV52860432; called by muse, mutect2, varscan2
- MAN2A1 | c.1768C>T p.H590Y | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV54851990; called by muse, mutect2, varscan2
- MAP2K1 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100199196, COSV61069845; called by muse, mutect2, varscan2
- MAP3K15 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV100135312; called by muse, mutect2, varscan2
- MERTK | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV99775042; called by muse, mutect2, varscan2
- MERTK | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54930470; called by muse, mutect2
- MIEF1 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100307785; called by muse, mutect2, varscan2
- MYH10 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1307836083, COSV99345922; called by muse, mutect2, varscan2
- NDN | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59360269; called by muse, mutect2, varscan2
- NOMO1 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV99814765; called by muse, mutect2, varscan2
- NPAP1 | c.2821A>T p.I941F | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV100275814; called by muse, mutect2, varscan2
- NPAS3 | c.191G>T p.R64L (on ENST00000356141 / NM_001164749.2; = p.R34L on NM_022123.3) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58118535; called by muse, mutect2, varscan2
- NRP2 | c.2731G>A p.E911K (on ENST00000360409 / NM_201266.2; = p.E906K on NM_003872.3) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1314551002, COSV63376199; called by muse, mutect2, varscan2
- ODAM | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772414978, COSV101258093; called by muse, mutect2, varscan2
- ODR4 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99834451; called by muse, mutect2, varscan2
- OGDH | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs377142006; called by mutect2, varscan2
- OR10X1 | c.314A>T p.D105V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV100936697; called by muse, mutect2, varscan2
- OR13F1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as rs1011561348, COSV58251317; called by muse, mutect2, varscan2
- OR1F1 | c.102G>C p.M34I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV100484482; called by muse, mutect2, varscan2
- OR2A12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV101283190; called by muse, mutect2, varscan2
- OR51I2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as rs145725236, COSV58298994; called by muse, mutect2, varscan2
- OR5D16 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1046156906, COSV101004089, COSV65722584; called by muse, mutect2, varscan2
- OR8B2 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100899461; called by muse, mutect2, varscan2
- OSMR | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.289); catalogued as COSV57091379; called by muse, mutect2, varscan2
- PARN | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100421244; called by muse, mutect2, varscan2
- PCDHB11 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61310995; called by muse, mutect2, varscan2
- PDE7B | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.601); catalogued as COSV57492347, COSV57499721; called by muse, mutect2, varscan2
- PHTF2 | c.158A>G p.Y53C (on ENST00000248550 / NM_001366089.1; = p.Y19C on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454030274, COSV99302135; called by muse, mutect2, varscan2
- PIK3C3 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100011390; called by muse, mutect2, varscan2
- PLSCR2 | c.599C>A p.P200Q (on ENST00000497985 / NM_001199978.1; = p.P127Q on NM_020359.2) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs760515235, COSV100367852, COSV60859619; called by muse, mutect2, varscan2
- PRAME | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV101287189; called by muse, mutect2, varscan2
- PRUNE2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs189759245, COSV65027738; called by muse, mutect2, varscan2
- PWWP3B | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1334873559, COSV100531495; called by muse, mutect2, varscan2
- RASA1 | c.801A>C p.K267N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV99170212; called by muse, mutect2, varscan2
- RECQL5 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100512201; called by muse, mutect2, varscan2
- RIMS1 | c.3709T>A p.S1237T | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1563639508, COSV99329206; called by muse, mutect2, varscan2
- RUSF1 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV59131808; called by muse, mutect2, varscan2
- RXFP2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53636791; called by muse, mutect2, varscan2
- SCN10A | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.397); catalogued as COSV71860407; called by muse, mutect2, varscan2
- SDK1 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67354512; called by muse, mutect2, varscan2
- SLCO1C1 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV99859622; called by muse, mutect2, varscan2
- SLIT1 | c.414G>A p.L138= | Splice Region (SNP) | VAF 13/19 reads (68%) | catalogued as rs1336444524, COSV99822115; called by muse, mutect2, varscan2
- SLITRK1 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV101000024; called by muse, mutect2, varscan2
- SPEF2 | c.3856G>A p.A1286T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs545231726, COSV100608318; called by muse, mutect2, varscan2
- SPINK13 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1367475523, COSV101268313; called by muse, mutect2, varscan2
- SRCIN1 | c.3352C>T p.R1118C (on ENST00000621492; = p.R1084C on NM_025248.3) | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1195040919; called by muse, mutect2, varscan2
- SRRM1 | c.1894A>G p.K632E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); catalogued as COSV100104982; called by muse, mutect2, varscan2
- STEAP4 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs924562362, COSV57329235; called by muse, mutect2, varscan2
- TGFB2 | c.1008C>G p.H336Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100860362; called by muse, mutect2, varscan2
- THBS1 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99528230; called by muse, mutect2, varscan2
- TLL1 | c.1380G>A p.A460= | Splice Region (SNP) | VAF 47/113 reads (42%) | catalogued as rs1478276075, COSV99288445; called by muse, mutect2, varscan2
- TNS4 | c.1247G>A p.S416N | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs760144986, COSV99564029; called by muse, mutect2, varscan2
- TP53BP1 | c.5531G>A p.R1844H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756730049, COSV99538594; called by muse, mutect2, varscan2
- TRAPPC11 | c.1558C>T p.L520F | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1190251259, COSV100591983; called by muse, mutect2, varscan2
- TRAPPC12 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV60847541; called by muse, mutect2
- TRPM6 | c.2411G>A p.R804K | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100666728, COSV62516823; called by muse, mutect2, varscan2
- TTN | c.24814G>A p.E8272K (on ENST00000591111; = p.E7345K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | PolyPhen benign (0.007); catalogued as COSV60072415; called by muse, mutect2, varscan2
- TTN | c.16559G>A p.G5520E (on ENST00000591111; = p.G4593E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | PolyPhen possibly damaging (0.811); catalogued as COSV60260706; called by muse, mutect2, varscan2
- U2SURP | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV101204539; called by muse, mutect2, varscan2
- ULK1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs758686407, COSV58856055; called by muse, mutect2, varscan2
- USP34 | c.8872G>A p.D2958N | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101277133; called by muse, mutect2, varscan2
- XPOT | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1260392101, COSV100225686; called by muse, mutect2, varscan2
- ZNF12 | c.631C>T p.R211C (on ENST00000405858 / NM_016265.4; = p.R173C on NM_006956.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs369502322, COSV61243669; called by muse, mutect2, varscan2
- ZNF296 | c.1228G>T p.G410W | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767877324, COSV99674033; called by muse, mutect2, varscan2
- ZNF366 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as COSV100574371; called by muse, mutect2, varscan2
- ZPLD1 | c.725A>C p.N242T (on ENST00000466937 / NM_001329788.1; = p.N258T on NM_175056.2) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.814); catalogued as COSV100083441; called by muse, mutect2, varscan2
- PUF60 | c.1451_1452del p.T484Rfs*40 (on ENST00000526683 / NM_001362896.2; = p.T467Rfs*40 on NM_014281.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 59/156 reads (38%) | called by mutect2, pindel, varscan2
- RBM12 | c.2667del p.K889Nfs*29 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- ACSS2 | c.726C>T p.F242= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99490052; called by muse, mutect2, varscan2
- ADAMDEC1 | c.822G>A p.G274= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56474607; called by muse, mutect2, varscan2
- ALG10 | c.162C>T p.S54= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs776308543, COSV99848273; called by muse, mutect2, varscan2
- AMIGO2 | c.411C>T p.F137= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV56974265; called by muse, mutect2, varscan2
- ANK2 | c.10479A>T p.T3493= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100003192; called by muse, mutect2, varscan2
- ANO10 | c.654C>T p.F218= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99428820; called by muse, mutect2, varscan2
- BPIFA3 | c.552G>A p.K184= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs1278301304, COSV100967101; called by muse, mutect2, varscan2
- BTBD2 | c.1383C>T p.P461= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1301382421, COSV99724890; called by muse, mutect2, varscan2
- C1QC | c.573C>T p.T191= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV101009514; called by muse, mutect2, varscan2
- CACNA1G | c.1761G>A p.G587= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1387627975, COSV100662257; called by muse, mutect2, varscan2
- CHRM3 | c.1440G>A p.R480= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV55078890, COSV99699174; called by muse, mutect2, varscan2
- CNTN4 | c.2592C>T p.I864= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100639517; called by muse, mutect2, varscan2
- COL12A1 | c.4752C>T p.V1584= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV100486307; called by muse, mutect2, varscan2
- COL4A3 | c.438C>T p.I146= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1171360432, COSV101170467; called by muse, mutect2
- DGAT1 | c.933C>T p.F311= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1341828948, COSV100184136; called by muse, mutect2, varscan2
- DMBT1 | c.5022G>A p.V1674= (on ENST00000338354 / NM_001377530.1; = p.V917= on NM_004406.3) | Silent (SNP) | VAF 167/225 reads (74%) | catalogued as COSV100353719; called by muse, mutect2, varscan2
- DNAH5 | c.6234G>A p.G2078= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99452385; called by muse, mutect2, varscan2
- DOCK3 | c.2979C>T p.F993= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1223459250, COSV56514848; called by muse, mutect2, varscan2
- ENTPD2 | c.1464C>T p.S488= (on ENST00000355097 / NM_203468.3; = p.S465= on NM_001246.4) | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1339649464, COSV57074881; called by muse, varscan2
- ERICH3 | c.3810C>T p.T1270= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100445144; called by muse, mutect2, varscan2
- EXOC3 | c.2143C>T p.L715= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- FAM135B | c.1689C>A p.P563= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV99426140; called by muse, mutect2, varscan2
- FARP2 | c.1383C>T p.L461= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs766057038, COSV99885144; called by muse, mutect2, varscan2
- FGF1 | c.303G>A p.L101= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs745432170, COSV100532453; called by muse, mutect2, varscan2
- GBF1 | c.588A>G p.L196= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV100890593; called by muse, mutect2, varscan2
- GLDN | c.570G>A p.G190= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100117944; called by muse, mutect2, varscan2
- GPR84 | c.924G>A p.P308= | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as rs749770390, COSV99910106; called by muse, mutect2, varscan2
- GPRIN2 | c.831G>A p.K277= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs782031260, COSV100966445, COSV65402385; called by muse, mutect2, varscan2
- IFITM1 | c.114C>A p.V38= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100068294; called by muse, mutect2, varscan2
- IGHV2-70 | c.285C>A p.S95= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs764689337; called by muse, mutect2, varscan2
- IGHV3-23 | c.33G>A p.V11= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as rs562374158; called by muse, mutect2, varscan2
- IL11RA | c.909C>T p.T303= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99426552; called by muse, mutect2, varscan2
- ITGB8 | c.429G>A p.K143= | Silent (SNP) | VAF 77/135 reads (57%) | catalogued as rs1218527045, COSV99752017; called by muse, mutect2, varscan2
- KCNG1 | c.528C>T p.F176= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs1444171112, COSV65368575; called by muse, mutect2, varscan2
- KIF13B | c.5370G>A p.R1790= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV68094837; called by muse, mutect2, varscan2
- LRP2 | c.10156C>T p.L3386= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99789680, COSV99790475; called by muse, mutect2, varscan2
- LRRC40 | c.1486A>C p.R496= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100918823; called by muse, mutect2, varscan2
- MANBA | c.1614C>T p.L538= (on ENST00000642252; = p.L492= on NM_005908.4) | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs760944138, COSV99898800; called by muse, mutect2, varscan2
- MCM2 | c.2700C>T p.I900= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs376562317; called by muse, mutect2, varscan2
- MLLT10 | c.1167C>T p.H389= | Silent (SNP) | VAF 61/88 reads (69%) | catalogued as COSV100308544; called by muse, mutect2, varscan2
- MROH8 | c.1320C>T p.I440= | Silent (SNP) | VAF 81/200 reads (41%) | catalogued as rs373432593; called by muse, mutect2, varscan2
- MYOCD | c.2724C>T p.T908= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100591166; called by muse, mutect2, varscan2
- MYRF | c.753C>T p.H251= (on ENST00000278836 / NM_001127392.3; = p.H242= on NM_013279.4) | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs1345199993, COSV99607556; called by muse, mutect2, varscan2
- NCAN | c.2370G>A p.L790= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV53052388, COSV53055021; called by muse, mutect2, varscan2
- NPAS3 | c.192G>A p.R64= (on ENST00000356141 / NM_001164749.2; = p.R34= on NM_022123.3) | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV58089562; called by muse, mutect2, varscan2
- OAS1 | c.1164C>T p.T388= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs779628553, COSV99177227; called by muse, mutect2, varscan2
- OPRK1 | c.1119C>T p.I373= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs150426309; called by muse, mutect2, varscan2
- OR5L2 | c.84C>T p.F28= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as COSV65724567; called by muse, mutect2, varscan2
- OSBPL11 | c.1356C>T p.I452= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99954426; called by muse, mutect2, varscan2
- PCDH19 | c.1254A>G p.Q418= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV99720459; called by muse, mutect2, varscan2
- PCLO | c.11250G>A p.R3750= | Silent (SNP) | VAF 40/61 reads (66%) | catalogued as rs764731077, COSV61657434, COSV61683646; called by muse, mutect2, varscan2
- POLL | c.1702C>A p.R568= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs540905898, COSV100150323, COSV100150392; called by muse, mutect2, varscan2
- POLL | c.1701C>T p.Y567= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as COSV100150393; called by muse, mutect2, varscan2
- RBL2 | c.2562C>T p.L854= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as COSV100043930; called by muse, mutect2
- RORC | c.798C>T p.S266= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100562040; called by muse, mutect2, varscan2
- RTN3 | c.270T>A p.S90= (on ENST00000377819 / NM_001265589.2; = p.S71= on NM_201428.3) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1196562047, COSV100127488; called by muse, mutect2, varscan2
- SLC8A3 | c.39C>T p.F13= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100776309; called by muse, mutect2, varscan2
- TCF4 | c.1944C>T p.L648= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV100610635; called by muse, mutect2, varscan2
- TMEM169 | c.537T>C p.S179= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV99824598; called by muse, mutect2, varscan2
- TMPRSS9 | c.3141G>A p.L1047= (on ENST00000648592; = p.L1013= on NM_182973.2) | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs749385990, COSV99296071; called by muse, mutect2, varscan2
- UCK2 | c.219G>A p.K73= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100903023; called by muse, mutect2, varscan2
- XCR1 | c.604C>T p.L202= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100499433, COSV100499519; called by muse, mutect2, varscan2
- ZNF202 | c.1809T>C p.S603= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100279113; called by muse, mutect2, varscan2
- ZNF749 | c.1512C>T p.I504= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV61945407; called by muse, mutect2, varscan2
- ZNF99 | c.1104C>A p.P368= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV101233907, COSV68056170; called by muse, mutect2, varscan2
- NXF5 | n.1374C>T | RNA (SNP) | VAF 51/152 reads (34%) | catalogued as COSV53789585; called by muse, mutect2, varscan2
- NXF5 | n.1373T>C | RNA (SNP) | VAF 51/150 reads (34%) | catalogued as COSV99534551; called by muse, mutect2, varscan2
- SLC35A3 | c.*636C>T | 3'UTR (SNP) | VAF 15/47 reads (32%) | catalogued as rs780108041, COSV64515958; called by muse, mutect2, varscan2
- SLCO1A2 | c.1675+20C>T | Intron (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100262431; called by muse, mutect2, varscan2
- TCF7 | c.1027-219C>T | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- TMPRSS3 | chr21:42396083 G>A | 5'Flank (SNP) | VAF 22/28 reads (79%) | catalogued as COSV99368447; called by muse, mutect2, varscan2
- TTN | c.10360+4083G>A | Intron (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100598233; called by muse, mutect2, varscan2
